FM case AD12904 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/bf6e42b1-6f61-40cf-8f00-ecb34ca5cb25

Female, 70.4 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the breast; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
